Somatic mutation profile of tumor specimen TARGET-10-PAPGEE-09A (aliquot TARGET-10-PAPGEE-09A-01D) from TARGET case TARGET-10-PAPGEE, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 9.0 years (3,291 days).
Specimen TARGET-10-PAPGEE-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a9891657-e038-4205-9cd0-12766554a87a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PAPGEE-10A (Blood Derived Normal), aliquot TARGET-10-PAPGEE-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/677b4345-8580-476f-b6cd-2089b53151c3

The open-access MAF lists 21 somatic variants for this specimen: 7 protein-altering or splice-affecting, 9 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Silent 9, Missense Mutation 5, Intron 3, In Frame Ins 2, 3'Flank 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CUZD1 | c.1532G>T p.R511L | Missense Mutation (SNP) | VAF 34/76 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs201005450; called by muse, mutect2, varscan2
- DUSP12 | c.57C>G p.S19R | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as COSV63411158; called by mutect2, varscan2
- FAM184A | c.2030G>A p.R677Q | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT tolerated (0.69); PolyPhen probably damaging (0.993); catalogued as rs779916036, COSV100138500; called by muse, mutect2, varscan2
- DUSP12 | c.56_57insGGG p.S19delinsRG | In Frame Ins (INS) | VAF 12/32 reads (38%) | called by mutect2, varscan2
- ERG | c.400_401insGCCCTTTGGACGCCG p.I133_V134insGPLDA | In Frame Ins (INS) | VAF 6/14 reads (43%) | called by mutect2, varscan2
- FAM83B | c.391C>T p.H131Y | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.357); called by muse, mutect2, varscan2
- IKZF1 | c.1394_1399delinsGGAGGG p.E465_C467delinsGRG | Missense Mutation (ONP) | VAF 26/74 reads (35%) | called by pindel, varscan2*
- ABCA10 | c.3264T>C p.Y1088= | Silent (SNP) | VAF 24/46 reads (52%) | called by muse, mutect2, varscan2
- ADAM12 | c.1020T>C p.N340= | Silent (SNP) | VAF 13/29 reads (45%) | called by muse, mutect2, varscan2
- ASB15 | c.528G>A p.K176= | Silent (SNP) | VAF 34/73 reads (47%) | catalogued as rs746570652; called by muse, mutect2, varscan2
- CHST11 | c.711C>T p.F237= | Silent (SNP) | VAF 42/103 reads (41%) | catalogued as COSV57985343; called by muse, mutect2, varscan2
- FAT1 | c.13230A>T p.T4410= | Silent (SNP) | VAF 15/40 reads (38%) | called by muse, mutect2, varscan2
- IGHV3-23 | c.336A>G p.V112= | Silent (SNP) | VAF 4/15 reads (27%) | catalogued as rs782239949; called by muse, varscan2
- MXRA8 | c.858C>G p.V286= | Silent (SNP) | VAF 4/34 reads (12%) | called by muse, mutect2
- NMNAT2 | c.36C>T p.L12= | Silent (SNP) | VAF 18/43 reads (42%) | called by muse, mutect2, varscan2
- NXPE1 | c.1530C>T p.N510= (on ENST00000424269; = p.N368= on NM_152315.5) | Silent (SNP) | VAF 53/117 reads (45%) | catalogued as rs765591762; called by muse, mutect2, varscan2
- COPRS | c.99+335G>A | Intron (SNP) | VAF 17/53 reads (32%) | called by muse, mutect2, varscan2
- IGHV1-69D | chr14:106762091 ins GAA | 3'Flank (INS) | VAF 21/29 reads (72%) | called by pindel, varscan2
- NCAN | c.*325G>C | 3'UTR (SNP) | VAF 6/13 reads (46%) | called by muse, mutect2, varscan2
- NLRP12 | c.2073-77C>T | Intron (SNP) | VAF 6/26 reads (23%) | catalogued as rs776713905, COSV60755618; called by muse, varscan2
- PDGFRA | c.628+15T>C | Intron (SNP) | VAF 22/51 reads (43%) | called by muse, mutect2, varscan2
